TARGET case TARGET-10-PARLZG — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6166f0ee-7e05-5937-aada-4395fd7fbba8

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 11 years; Vital status: Dead; Days to death: 1,546 days (4.2 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.2 years (4,093 days); Year of diagnosis: 2007; Days to last follow up: 1,546 days (4.2 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 1,003 days (2.7 years); Days to first event: 1,003 days (2.7 years); First event: Relapse.
- Days to follow up: 1,546 days (4.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Positive.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 12.9 ×10³/µL.
- Day 8: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0.06%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.45%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (4 samples)
- Sample TARGET-10-PARLZG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PARLZG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARLZG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARLZG-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 1546
- WBC at Diagnosis: 12.9
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 0.06
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.45
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Positive
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 2
- BMA Blasts Day 29: 0
- Karyotype: 46,XX,add(1)(q21),t(1;19)(q23;p13.3)[6]/46,XX,t(1;19)(q23;p13.3),-15,+mar[4]/46,XX[10]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: TCF3-PBX1
